TARGET case TARGET-30-PAPYNZ — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ccedcc8b-429a-5aa0-b0db-6ab1d4e49398

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Dead; Days to death: 336 days.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C76.2; Tissue or organ of origin: Abdomen, NOS; Classification of tumor: primary; Age at diagnosis: 2.8 years (1,024 days); Year of diagnosis: 2007; Days to last follow up: 336 days; Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Pathology details: Necrosis percent: 0; Percent tumor nuclei: 0.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 312 days; Days to first event: 312 days; First event: Relapse.
- Days to follow up: 336 days; Year of follow up: 2007.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAPYNZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAPYNZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 336
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.72
- Histology: Unfavorable
- ICDO Description: Abdomen, NOS Abdominal wall, NOS Intra-abdominal site, NOS
- Percent Tumor: 0
- Percent Necrosis: 0
- Percent Tumor v/s Stroma: 0/100
- Site of Relapse: Other Metastatic Sites
